Somatic mutation profile of tumor specimen TCGA-WB-A817-01A (aliquot TCGA-WB-A817-01A-11D-A35I-08) from TCGA case TCGA-WB-A817, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 27.3 years (9,981 days).
Specimen TCGA-WB-A817-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aeb3ccc1-1251-4c4b-a4bc-72e673adc5da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A817-10A (Blood Derived Normal), aliquot TCGA-WB-A817-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b14216a6-2705-4e92-b6b7-0940fd2d0673

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MGA | c.4843A>G p.M1615V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764853257; called by muse, mutect2, varscan2
- CACNA1D | c.1947_1955del p.I650_S652del (on ENST00000350061 / NM_001128840.3; = p.I670_S672del on NM_000720.4) | In Frame Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- CD300C | c.423C>A p.S141R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RANBP2 | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DNER | c.1662C>T p.N554= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs528523117, COSV59163503; called by muse, mutect2, varscan2
